CCDI case PBCDAZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/d9bff10c-f97d-4154-b217-66a58fedb877

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 17.3 years (6,305 days).

Biospecimens (3 samples)
- Sample 0DP0MS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP0N1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP0N6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
